FM case AD15333 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Basal Cell Neoplasms; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/dadef242-7925-4230-9829-d9224efacecc

Male, 56.7 years: Basal cell carcinoma, NOS (ICD-O-3 8090/3) of the skin; metastasis biopsied or resected from the head, face or neck. Tumor nuclei on the sequenced sample's slide: 43% (pathologist estimate recorded by GDC). Sample type: Metastatic.
